Surgical pathology report (de-identified scan), TCGA case TCGA-Q1-A73Q, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q1-A73Q-01A (Primary Tumor).

[page 1 of 2]
RUN DATE:
RUN TIME:
BY:

PAGE:1

SPEC #:
STATUS:

Obtained:
Received:

Subm Dr:

CLINICAL HISTORY:
CYSTO/PROCTO

SPECIMEN/PROCEDURE:

1. CERVICAL BIOPSY
2. CERVICAL BIOPSY

. ICD-O-3
Carcinoma, squamous cell
keratinizing 8071/3
Site Cervix Nbs C53.9
W8/15/13

IMPRESSION:

- 1) CERVIX, BIOPSY:
- . Invasive squamous cell carcinoma, focally keratinizing; moderately to poorly differentiated; ulcerated with prominent acute and chronic inflammation.
- . Lymphovascular invasion is not identified.
- 2) CERVIX, BIOPSY;
- . Invasive squamous cell carcinoma, focally keratinizing; moderately to poorly differentiated.
- . Lymphovascular invasion is not identified.

Dictated by:
Entered:

COMMENT:

Representative section reviewed by _____ at _____

Entered:

SPECIAL STAINS/PROCEDURES:

The following immunohistochemical stain is performed with appropriate positive and negative controls on block 1B:

p63:

Strong diffuse nuclear staining (supporting the H&E impression of squamous cell carcinoma and ruling against neuroendocrine small cell carcinoma).

Dictated by:

GROSS DESCRIPTION:

1. Received in formalin labeled "cervical biopsy" and with the patient's name, the specimen consists of 3 fragments of pink to red hemorrhagic friable tissue ranging in size from 0.7 x 0.2 x 0.2 cm to 1.6 x 1.3 x 0.7 cm. The larger fragments are sectioned and the specimen is entirely submitted in three cassettes.

** CONTINUED ON NEXT PAGE **

[page 2 of 2]
GROSS DESCRIPTION: (continued)

2. Received in formalin labeled "cervical biopsy" and with the patient's name, the specimen consists of multiple fragments of pink to red hemorrhagic friable tissue measuring 2.5 x 1.5 x 0.6 cm in aggregate. The largest fragment is partially surfaced by pale tan grossly unremarkable mucosa. The resection margin is inked black and the specimen is trisected to reveal pale tan cut surfaces. The specimen is entirely submitted in two cassettes.

Dictated by:

Entered:

COPIES TO:

CPT Codes:

IHC P63-88342, CERVICAL BIOPSY/88305/2, NEG MAB CONTROL

ICD9 Codes:

180.9

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by: _____

** END OF REPORT **

HPVAA D discrepancy		/

Source: NCI Genomic Data Commons file a88589ab-ab46-4fbb-a798-f57b2140dbac (TCGA-Q1-A73Q.C29EC084-5A50-4007-B281-391965A67F43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).